CTSP case CTSP-B02I — CTSP-DLBCL1: CTSP Diffuse Large B-Cell Lymphoma (DLBCL) CALGB 50303
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Mature B-Cell Lymphomas. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/e198a237-2675-4e8e-a903-d76b66da8a61

Demographics
Sex at birth: male; Race: asian; Ethnicity: not hispanic or latino; Year of birth: 1931; Vital status: Alive.

Diagnoses (1)
1. Diffuse large B-cell lymphoma, NOS: ICD-O-3 morphology code: 9680/3; Age at diagnosis: 75.1 years (27,426 days); Method of diagnosis: Biopsy; Ann Arbor pathologic stage: Stage III; Days to last follow up: 1,962 days (5.4 years); Ann Arbor extranodal involvement: No; International Prognostic Index (IPI): High Risk.

Biospecimens (1 sample)
- Sample DLBCL11295-sample: Sample type: Tumor; Tissue type: Tumor.
